TCGA case TCGA-R6-A6Y0 — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/77b3ec30-1e9f-466a-944b-6b187635edb7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 54.9 years (20,045 days); Year of diagnosis: 2005; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC clinical T: T3; AJCC clinical N: N1; AJCC clinical M: M1a; AJCC clinical stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,641 days (4.5 years); Cancer detection method: Symptomatic; Esophageal columnar dysplasia degree: Negative/ No Dysplasia; Esophageal columnar metaplasia present: No; Goblet cells columnar mucosa present: No; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS; Surgery, NOS.

Follow-up (1 entry)
- Days to follow up: 1,641 days (4.5 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 94 kg; Height: 173 cm; BMI: 31.4.

Exposures
- Alcohol history: Yes; Alcohol days per week: 1.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-R6-A6Y0-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 5 mg.
  Slide TCGA-R6-A6Y0-01Z-00-DX1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 13; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 6; Percent neutrophil infiltration: 2.
- Sample TCGA-R6-A6Y0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-R6-A6Y0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: TX; Cancer procurement city: Houston; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 1; Alcohol consumption frequency: 1; History reflux disease indicator: No; History hpylori infection indicator: Never; History barretts esophageal indicator: No; Number of relatives diagnosed: 0; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Esoph non CA degree of dysplasia: Negative/no dysplasia; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: No; Patient to undergo surgery: No.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor; Treatment outcome first course: Stable Disease; Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,641 days; disease-specific survival: no event (censored), 1,641 days; progression-free interval: no event (censored), 1,641 days.
